Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4327, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4327-01A (Primary Tumor).

[page 1 of 2]
.....
Other Related Data:

Billing Type: [REDACTED]

Financial Number:

[REDACTED] & History:

[REDACTED] with right renal tumor.

Specimens Submitted:

1: SP: Right kidney [REDACTED]

2: SP: Paracaval lymph nodes [REDACTED]

DIAGNOSIS:

- 1) KIDNEY, RIGHT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE II/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR'S GREATEST DIAMETER IS 7.5 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS NOT IDENTIFIED.
- 2) LYMPH NODES, PARACAVAL; DISSECTION:
- SIX BENIGN LYMPH NODES (0/6).

[REDACTED]

Gross Description:

[REDACTED]

1) The specimen is received fresh, labeled "Right Kidney". It consists of a kidney and perirenal fat measuring 15 x 10 x 7 cm and weighing 400 grams overall. A portion of unremarkable ureter measures 8 x 0.4 x 0.3 cm. A portion of unremarkable renal vein measures 1 cm in length and 1 cm in diameter. Adrenal gland is not identified. The specimen is bivalved showing partly yellow and partly light tan to brown, focally hemorrhagic and necrotic tumor measuring 7.5 x 5.5 x 4 cm. The tumor is cortical in

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

location and has irregular borders with lobulated appearance. The Gerota's fascia around the tumor is inked black. The tumor protrudes the renal capsule. It is confined within the Gerota's fascia. The distance from the tumor to the nearest Gerota's fascia is 0.2 cm and to the renal pelvis 0.3 cm. The renal vein is uninvolved. The specimen is photographed. Representative sections are submitted. Fresh tissue is saved for TPS and EM.

Summary of Sections:

UM - ureteral margin
RVM - renal vein margin
TRC - tumor renal capsule
TP - tumor renal pelvis
TG - tumor Gerota's fascia
TN - tumor normal kidney
N - normal kidney
T - additional tumor

2) The specimen is received in formalin, labeled "Paracaval Lymph Nodes". It consists of two pieces of fibroadipose tissue measuring 1.5 x 1 x 1 cm and 3 x 2 x 1 cm. Few lymph nodes are identified that range in size from 0.3 to 0.4 cm in largest dimension. Lymph nodes are submitted in toto.

Summary of Sections:

LNS - lymph nodes

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	N		1	2	
	RVM		1	1	
	T		6	6	
	TG		2	2	
	TN		1	1	
	TP		1	2	
	TRC		2	2	
	UM		1	1	
2	LNS		1	M	N

Source: NCI Genomic Data Commons file b2f8dfbf-ed91-4253-ad44-78776528e59e (TCGA-BP-4327.5E65EF69-17B3-4144-A651-6CF1B511ED4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).